Gene-level copy-number profile of tumor specimen TCGA-2J-AABF-01A from TCGA case TCGA-2J-AABF, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 73.7 years (26,936 days).
Specimen TCGA-2J-AABF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.6e93d202-bbe1-439e-82b6-1f0bf8be4524.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2J-AABF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/901b6435-8548-4032-856c-fa5b7130b605

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 6,216; copy number 2: 34,425; copy number 3: 16,880; copy number 4: 2,162; copy number 5: 14; copy number 6: 80; copy number 7: 7; copy number 8: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2J-AABF-01A-31D-A40V-01): tumor purity 0.32, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,314,246–10,612,723, 1 gene (within-gene range 0–1): PTPRD.
- chr9:9,442,060–12,159,148, 14 genes: RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 121 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:106,271,634–107,133,170, 21 genes, copy number 5–7: U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P.
- chr11:68,612,899–71,928,654, 100 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,216. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
